Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4763, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4763-01A (Primary Tumor).

[page 1 of 2]
...

Clinical Diagnosis & History:

with large right renal mass

Specimens Submitted:

1: SP: Tumor, right kidney for diagnosis

2: SP: Right kidney cyst wall

DIAGNOSIS:

- 1) KIDNEY, RIGHT; PARTIAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, CLEAR CELL (CONVENTIONAL) TYPE, NUCLEAR GRADE III/IV.
- THE PATTERN OF GROWTH IS SOLID.
- THE TUMOR GREATEST DIAMETER IS 2.2 CM.
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- THE SURGICAL MARGIN IS FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- 2) CYST WALL, RIGHT KIDNEY; EXCISION:
- BENIGN RENAL PARENCHYMA WITH BENIGN CYST.

Special Studies:

Result	Special Stain	Comment
--------	---------------	---------

	RECUT	
--	-------	--

1) The specimen is received fresh for frozen section, labeled "Tumor, right kidney for diagnosis. Stitch marks deep margin". It consists of a partial nephrectomy with attached perinephric fat, measuring 15 x 8 x 4 cm overall, with a 5.0 x 4.5 x 3.0 cm portion of kidney. The deep margin is inked black. The specimen is sectioned to reveal a 2.2 x 1.9 x 1.2 cm circumscribed, tan-yellow mass with foci of hemorrhage. It is grossly 0.4 cm from the inked stitched margin of resection. The mass is grossly confined to the kidney and does not extend into the perinephric fat. A portion is submitted for . A portion is fixed in EM fixative for possible future studies if necessary.

Summary of Sections:

FSC - Frozen section control

M - Mass

[page 2 of 2]
NK - Normal kidney

2) The specimen is received in formalin, labeled "Right kidney, cyst wall". It consists of a 0.8 x 0.4 x 0.2 cm tan-white soft tissue fragment which is entirely submitted.

Summary of Sections:

CW - Cyst wall

Summary of Sections:

Part 1: SP: Tumor, right kidney for diagnosis (

Block	Sect. Site	PCs
1	fsc	1
5	m	5
1	nk	1

Part 2: SP: Right kidney cyst wall

Block	Sect. Site	PCs
1	cw	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL NEOPLASM. MARGIN FREE OF TUMOR.
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file b1b97b0f-a3f8-41b0-8001-ad121bbe6c55 (TCGA-BP-4763.B852166F-5F68-425D-83C3-FA6F4D2A34F7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).